Somatic mutation profile of tumor specimen TCGA-06-5858-01A (aliquot TCGA-06-5858-01A-01D-1696-08) from TCGA case TCGA-06-5858, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 45.6 years (16,662 days).
Specimen TCGA-06-5858-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 780904e4-194a-49b7-bdfc-3ab991768af9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-5858-10A (Blood Derived Normal), aliquot TCGA-06-5858-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7280605-858e-4595-82db-e7508d9a8f57

The open-access MAF lists 199 somatic variants for this specimen: 133 protein-altering or splice-affecting, 62 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 123, Silent 62, Nonsense Mutation 5, Frame Shift Ins 2, Intron 2, Frame Shift Del 1, RNA 1, Splice Region 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CENPF | c.9280C>T p.R3094* | Nonsense Mutation (SNP) | VAF 31/40 reads (78%) | catalogued as rs869312748, CM162211, COSV65276590; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNPAT | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 74/98 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1442079596, COSV64153814; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.3261del p.F1088Sfs*2 | Frame Shift Del (DEL) | VAF 58/78 reads (74%) | hotspot (GDC flag); catalogued as rs267608078, COSV99029757; ClinVar: pathogenic; called by mutect2, varscan2
- NPC1 | c.2873G>A p.R958Q | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs120074132, CM015186, CM020045; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 104/137 reads (76%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- RB1 | c.1215+1G>A p.X405_splice | Splice Site (SNP) | VAF 87/119 reads (73%) | hotspot (GDC flag); catalogued as rs587776783, CS890133, CS982341, COSV57294684, COSV57294939, COSV57306748; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 57/83 reads (69%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AATK | c.2932C>T p.R978W (on ENST00000326724 / NM_001080395.3; = p.R875W on NM_004920.2) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as rs368177200; called by muse, mutect2, varscan2
- ABCC4 | c.3947C>T p.S1316L | Missense Mutation (SNP) | VAF 71/93 reads (76%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.079); catalogued as rs1454130025, COSV65315403; called by muse, mutect2, varscan2
- ACER2 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 160/220 reads (73%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs145427232, COSV61820375; called by muse, mutect2, varscan2
- ADAMTS5 | c.244T>G p.S82A | Missense Mutation (SNP) | VAF 87/117 reads (74%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV53181224; called by muse, mutect2, varscan2
- ADD1 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 68/97 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767055661, COSV53271278; called by muse, mutect2, varscan2
- ADGRF5 | c.1604C>T p.S535L | Missense Mutation (SNP) | VAF 76/97 reads (78%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as rs570716966, COSV51934126; called by muse, mutect2, varscan2
- AFDN | c.3632C>T p.T1211M | Missense Mutation (SNP) | VAF 35/56 reads (63%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.143); catalogued as rs145954704; called by muse, mutect2, varscan2
- ARHGAP25 | c.529G>A p.V177M (on ENST00000409202 / NM_001007231.3; = p.V169M on NM_014882.3) | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV54904924; called by muse, mutect2
- ARHGDIA | c.587T>G p.L196R | Missense Mutation (SNP) | VAF 60/74 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53907315; called by muse, mutect2, varscan2
- ARHGEF7 | c.716G>A p.R239H (on ENST00000375741 / NM_001113511.2; = p.R61H on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/46 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs759964144, COSV54546823; called by muse, mutect2, varscan2
- ARID3B | c.1658C>T p.A553V (on ENST00000622429 / NM_001307939.1; = p.A552V on NM_006465.4) | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as COSV60558270; called by muse, mutect2, varscan2
- ASAP2 | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 110/165 reads (67%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.975); catalogued as rs919010572, COSV55634729, COSV55636496; called by muse, mutect2, varscan2
- ASB5 | c.279T>C p.G93= | Splice Region (SNP) | VAF 10/81 reads (12%) | catalogued as COSV56672491; called by muse, mutect2, varscan2
- ATG16L2 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 44/52 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs532590002, COSV58362352; called by muse, mutect2, varscan2
- ATRX | c.6457C>T p.R2153C | Missense Mutation (SNP) | VAF 86/127 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64872312, COSV64880905; called by muse, mutect2, varscan2
- BCL6 | c.1918C>T p.R640W | Missense Mutation (SNP) | VAF 83/116 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51652430; called by muse, mutect2, varscan2
- BLZF1 | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 37/49 reads (76%) | catalogued as rs763271139, COSV61393623; called by muse, mutect2, varscan2
- BMP15 | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 93/136 reads (68%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.767); catalogued as rs782724245, COSV53140921; called by muse, mutect2, varscan2
- BMP4 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 70/144 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs774938531, COSV55416549; called by muse, mutect2, varscan2
- BRCA1 | c.3608G>A p.R1203Q | Missense Mutation (SNP) | VAF 43/61 reads (70%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs55930959, CM042676, COSV58794111; ClinVar: conflicting interpretations of pathogenicity / likely benign / benign; called by muse, mutect2, varscan2
- C16orf54 | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 33/45 reads (73%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs774872519, COSV61477003; called by muse, mutect2, varscan2
- CALN1 | c.625G>A p.A209T (on ENST00000329008 / NM_001017440.3; = p.A251T on NM_031468.4) | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100209324, COSV61140975; called by muse, mutect2, varscan2
- CARM1 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 109/145 reads (75%) | SIFT tolerated (0.15); PolyPhen benign (0.091); catalogued as rs1457197793, COSV59001756; called by muse, mutect2, varscan2
- CCDC102A | c.1576C>T p.R526C | Missense Mutation (SNP) | VAF 108/142 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs777894501, COSV50777531; called by muse, varscan2
- CCDC180 | c.3911C>T p.P1304L | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs202030409; called by muse, mutect2, varscan2
- CD84 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751746966, COSV60867000; called by muse, mutect2
- CEP63 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370940310, COSV59674634; called by muse, mutect2, varscan2
- CFAP47 | c.2581C>T p.R861* | Nonsense Mutation (SNP) | VAF 209/288 reads (73%) | catalogued as COSV52884313; called by muse, mutect2, varscan2
- CHD1L | c.2570G>A p.R857Q | Missense Mutation (SNP) | VAF 12/239 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1180954265, COSV63614693; called by muse, mutect2
- CHRM4 | c.1418G>A p.R473Q | Missense Mutation (SNP) | VAF 34/44 reads (77%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as rs201159443, COSV58991347; called by muse, mutect2, varscan2
- CLCN6 | c.1288dup p.C430Lfs*4 | Frame Shift Ins (INS) | VAF 9/62 reads (15%) | catalogued as rs778208569; called by mutect2, varscan2
- CPXM2 | c.2263C>T p.R755C | Missense Mutation (SNP) | VAF 91/120 reads (76%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.649); catalogued as rs756593635, COSV53857826, COSV53865934; called by muse, mutect2, varscan2
- CSF2RB | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs774793372, COSV53255203, COSV53256118; called by muse, mutect2, varscan2
- CTTNBP2 | c.3797G>A p.R1266H | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs200782612, COSV50392485; called by muse, mutect2, varscan2
- DLG4 | c.1547G>A p.R516Q (on ENST00000399506 / NM_001321075.3; = p.R559Q on NM_001365.4) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1487554412, COSV57239765; called by muse, mutect2
- DNAJC16 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 45/60 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs776330570, COSV65449020; called by muse, mutect2, varscan2
- DSG1 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.479); catalogued as rs770916767, COSV57134860; called by muse, mutect2, varscan2
- EML2 | c.259G>A p.V87I | Missense Mutation (SNP) | VAF 41/60 reads (68%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs143778766; called by muse, mutect2, varscan2
- EPS15 | c.2219G>A p.R740H | Missense Mutation (SNP) | VAF 46/71 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as rs768038641, COSV65543675; called by muse, mutect2, varscan2
- FBXL17 | c.1414G>A p.G472S | Missense Mutation (SNP) | VAF 64/93 reads (69%) | SIFT tolerated (0.49); PolyPhen benign (0.429); catalogued as rs752740515, COSV62856457; called by muse, mutect2, varscan2
- FBXL19 | c.2014C>T p.R672W | Missense Mutation (SNP) | VAF 26/33 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57943965; called by muse, mutect2, varscan2
- FGF18 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 139/191 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758902974, COSV51126535; called by muse, mutect2, varscan2
- FILIP1L | c.2458C>T p.R820C (on ENST00000354552 / NM_182909.3; = p.R580C on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 111/239 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs374898848; called by muse, mutect2, varscan2
- FLNA | c.6601C>T p.R2201C (on ENST00000369850 / NM_001110556.2; = p.R2193C on NM_001456.3) | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs782621818, COSV61047109; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HIRA | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 15/431 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54277074; called by muse, mutect2
- HNRNPH3 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 121/163 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV56262166; called by muse, mutect2, varscan2
- HTR5A | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.21); catalogued as rs910479674, COSV55280189; called by muse, mutect2, varscan2
- IFT122 | c.1015G>A p.G339S (on ENST00000348417 / NM_052989.3; = p.G280S on NM_018262.4) | Missense Mutation (SNP) | VAF 78/129 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs749146926, COSV56205289; called by muse, mutect2, varscan2
- IGHD | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 50/63 reads (79%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as rs370667338; called by muse, mutect2, varscan2
- IL27RA | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 79/120 reads (66%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs201794701, COSV54601246; called by muse, mutect2, varscan2
- IL5RA | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 98/134 reads (73%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs569914205, COSV56523747, COSV56524951; called by muse, mutect2, varscan2
- ING1 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as rs779538748, COSV58167481; called by muse, mutect2
- INPPL1 | c.1831C>T p.R611C | Missense Mutation (SNP) | VAF 92/152 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771815535, COSV53357347; called by muse, mutect2, varscan2
- INSRR | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769822233, COSV63871900; called by muse, mutect2, varscan2
- KDM6B | c.2546C>T p.P849L | Missense Mutation (SNP) | VAF 88/115 reads (77%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs376654821; called by muse, mutect2, varscan2
- KIAA2026 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 70/87 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs772525005, COSV67353720; called by muse, mutect2, varscan2
- LRRC75A | c.575G>A p.R192Q (on ENST00000470794 / NM_001113567.3; = p.A153= on NM_207387.4) | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.552); catalogued as rs775338348, COSV63359158; called by muse, mutect2, varscan2
- MAST1 | c.1480G>A p.V494M | Missense Mutation (SNP) | VAF 74/91 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs755153742, COSV52250345; called by muse, mutect2, varscan2
- MAST4 | c.1684C>T p.R562* (on ENST00000403625 / NM_001164664.2; = p.R373* on NM_015183.3) | Nonsense Mutation (SNP) | VAF 16/20 reads (80%) | catalogued as rs1220527593, COSV55115087; called by mutect2, varscan2
- MC2R | c.432G>A p.M144I | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.119); catalogued as COSV59619118; called by muse, mutect2
- MICAL3 | c.3641C>T p.S1214L | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as rs746205918, COSV71588281; called by muse, mutect2, varscan2
- MRGPRE | c.302C>T p.T101M | Missense Mutation (SNP) | VAF 45/60 reads (75%) | SIFT tolerated (0.17); PolyPhen benign (0.048); catalogued as rs372934659, COSV101100046; called by muse, mutect2, varscan2
- MUC16 | c.39350C>T p.T13117I | Missense Mutation (SNP) | VAF 230/329 reads (70%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.22); catalogued as COSV66694542; called by muse, mutect2, varscan2
- NBEAL2 | c.3208C>T p.R1070C | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1323267930, COSV52760810; called by muse, mutect2, varscan2
- NCAPH2 | c.685G>A p.V229M | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.537); catalogued as rs574318930, COSV53219197; called by muse, mutect2, varscan2
- NELL1 | c.1039C>T p.R347W | Missense Mutation (SNP) | VAF 77/113 reads (68%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs1199157497, COSV54290404, COSV54327653; called by muse, mutect2, varscan2
- NEMF | c.2108C>T p.T703M | Missense Mutation (SNP) | VAF 81/106 reads (76%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as rs1470217099, COSV53593260; called by muse, mutect2, varscan2
- NOC2L | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 51/74 reads (69%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs755408287, COSV58989040; called by muse, mutect2, varscan2
- NOS2 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 138/175 reads (79%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs375397175; called by muse, mutect2, varscan2
- NPHS1 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 67/98 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV62288922; called by muse, mutect2, varscan2
- PARP4 | c.3064G>A p.G1022R | Missense Mutation (SNP) | VAF 66/91 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748091610, COSV67963052; called by muse, mutect2, varscan2
- PCDH19 | c.1510A>G p.T504A | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as COSV55266830; called by muse, mutect2, varscan2
- PCDHA3 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 104/137 reads (76%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV65368876; called by muse, mutect2, varscan2
- PCDHA4 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 106/145 reads (73%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.253); catalogued as COSV100793267, COSV63543593; called by muse, mutect2, varscan2
- PCDHB2 | c.1684T>A p.F562I | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV99166263; called by muse, mutect2, varscan2
- PCDHGA1 | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 20/207 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV65295131; called by muse, mutect2
- PCDHGA11 | c.1478C>T p.T493M | Missense Mutation (SNP) | VAF 81/109 reads (74%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.046); catalogued as rs371027437, COSV53984701; called by muse, mutect2, varscan2
- PDE6C | c.215A>G p.E72G | Missense Mutation (SNP) | VAF 49/80 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.104); catalogued as COSV101008831; called by mutect2, varscan2
- PDE8B | c.1876G>A p.A626T | Missense Mutation (SNP) | VAF 87/120 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376573598; called by muse, mutect2, varscan2
- PFKL | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1454312894, COSV62464301; called by muse, mutect2, varscan2
- PID1 | c.233C>T p.T78M (on ENST00000354069 / NM_001330156.1; = p.T76M on NM_017933.5) | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.869); catalogued as rs775417884, COSV62472692; called by muse, mutect2, varscan2
- PLEKHA7 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 238/295 reads (81%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1215225142, COSV63047338; called by muse, mutect2, varscan2
- PLPPR3 | c.1642G>A p.A548T (on ENST00000520876 / NM_001270366.2; = p.A576T on NM_024888.2) | Missense Mutation (SNP) | VAF 15/16 reads (94%) | SIFT tolerated (0.62); PolyPhen benign (0.043); catalogued as rs1314477849, COSV62460965; called by muse, mutect2, varscan2
- PNPLA7 | c.3514C>T p.R1172C | Missense Mutation (SNP) | VAF 62/86 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs188270302; called by muse, mutect2, varscan2
- PNPLA7 | c.2843C>T p.A948V | Missense Mutation (SNP) | VAF 65/96 reads (68%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as rs538892595, COSV53002204; called by muse, mutect2, varscan2
- POM121L12 | c.679G>T p.A227S | Missense Mutation (SNP) | VAF 82/179 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.047); catalogued as COSV68693472; called by muse, mutect2, varscan2
- PUDP | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT tolerated (0.7); PolyPhen benign (0.014); catalogued as rs182257555, COSV66903239; called by muse, mutect2
- RASGRP2 | c.1649G>A p.R550H | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs761076139, COSV62448729; called by muse, mutect2, varscan2
- RC3H2 | c.2720C>T p.A907V | Missense Mutation (SNP) | VAF 77/96 reads (80%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as COSV61801430; called by muse, mutect2, varscan2
- RIN3 | c.1897C>T p.R633C | Missense Mutation (SNP) | VAF 46/57 reads (81%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.893); catalogued as rs769093908, COSV53647380; called by muse, mutect2, varscan2
- RNF26 | c.265A>G p.S89G | Missense Mutation (SNP) | VAF 197/269 reads (73%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV60990975; called by muse, mutect2, varscan2
- SDK1 | c.2786G>A p.G929E | Missense Mutation (SNP) | VAF 22/316 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.843); catalogued as rs758889848, COSV67378638; called by muse, mutect2
- SIN3A | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs1210128185, COSV64583937; called by muse, mutect2, varscan2
- SLC27A1 | c.1661C>T p.A554V | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs757218318, COSV53098785; called by mutect2, varscan2
- SLC35B3 | c.421A>G p.I141V | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.326); catalogued as COSV59469014; called by muse, mutect2
- SLC4A2 | c.2596G>A p.G866S | Missense Mutation (SNP) | VAF 69/161 reads (43%) | SIFT tolerated (0.98); PolyPhen benign (0.029); catalogued as rs573998641, COSV52541035; called by muse, mutect2, varscan2
- SLC7A5 | c.937G>A p.V313M | Missense Mutation (SNP) | VAF 65/93 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs780213182, COSV55365457; called by muse, mutect2, varscan2
- SORCS1 | c.440C>A p.P147Q | Missense Mutation (SNP) | VAF 69/100 reads (69%) | SIFT tolerated (0.47); PolyPhen benign (0.044); catalogued as COSV53876810; called by muse, mutect2, varscan2
- STRBP | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 48/67 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62117279; called by muse, mutect2, varscan2
- SVEP1 | c.3301G>A p.V1101M | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.874); catalogued as rs773002647, COSV57041497; called by muse, mutect2, varscan2
- SYMPK | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 94/130 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1371759509, COSV55609332; called by muse, mutect2, varscan2
- SYMPK | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as COSV55613514; called by muse, mutect2, varscan2
- TAFA5 | c.188G>A p.R63Q (on ENST00000402357 / NM_001082967.3; = p.R56Q on NM_015381.7) | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as COSV60984987; called by muse, mutect2
- TANC1 | c.3319C>T p.R1107W | Missense Mutation (SNP) | VAF 17/188 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.849); catalogued as rs764599245, COSV55091944; called by muse, mutect2
- TBC1D8 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as rs774137261, COSV65211744; called by muse, mutect2
- TGDS | c.525T>G p.C175W | Missense Mutation (SNP) | VAF 55/96 reads (57%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.815); catalogued as COSV54301497; called by muse, mutect2, varscan2
- TLCD5 | c.688C>T p.R230W (on ENST00000375095 / NM_001198671.2; = p.R133W on NM_174926.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs369584063; called by muse, mutect2, varscan2
- TLNRD1 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as rs372825596; called by muse, mutect2, varscan2
- TP63 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 101/140 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs193921145, COSV53197756; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TPTE2 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 78/148 reads (53%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.006); catalogued as COSV55024425; called by muse, mutect2, varscan2
- TRAPPC8 | c.2449G>A p.E817K | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.09); catalogued as rs754962648, COSV51974320; called by muse, mutect2, varscan2
- TRMT1 | c.1760G>A p.R587Q | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.184); catalogued as rs748672881, COSV53400415; called by muse, mutect2, varscan2
- TSKS | c.1709C>T p.T570M | Missense Mutation (SNP) | VAF 102/140 reads (73%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.052); catalogued as rs141726866; called by muse, mutect2, varscan2
- TTC21A | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 46/61 reads (75%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs781132950, COSV57187218; called by muse, mutect2, varscan2
- TTN | c.99535G>A p.E33179K (on ENST00000591111; = p.E25755K on NM_003319.4) | Missense Mutation (SNP) | VAF 33/47 reads (70%) | PolyPhen benign (0.268); catalogued as rs766062367, COSV59951999; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP49 | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 58/90 reads (64%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750214578, COSV51899084; called by muse, mutect2, varscan2
- VANGL1 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 51/71 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs770589524, COSV59621285; called by muse, mutect2, varscan2
- VIPR2 | c.274A>G p.N92D | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs769716862, COSV51110858; called by muse, mutect2, varscan2
- VIRMA | c.3826C>T p.R1276C | Missense Mutation (SNP) | VAF 70/101 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as rs1284853938, COSV52582946; called by muse, mutect2, varscan2
- WDR73 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 40/54 reads (74%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs748057659, COSV62411321; called by muse, mutect2, varscan2
- ZAN | c.2695C>T p.L899F | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as rs944260991, COSV61811738; called by muse, mutect2, varscan2
- ZBED1 | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58136154; called by muse, mutect2, varscan2
- ZBED9 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 61/82 reads (74%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.997); catalogued as rs200336287, COSV71729235; called by muse, mutect2, varscan2
- ZFP42 | c.791C>T p.T264M | Missense Mutation (SNP) | VAF 48/63 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1052462774, COSV58817514; called by muse, mutect2, varscan2
- ZNF689 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 34/41 reads (83%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs774313641, COSV54908890; called by muse, mutect2, varscan2
- FBXO15 | c.1187dup p.N396Kfs*2 | Frame Shift Ins (INS) | VAF 33/95 reads (35%) | called by mutect2, pindel, varscan2
- AASS | c.102C>T p.N34= | Silent (SNP) | VAF 97/252 reads (38%) | catalogued as rs777413121, COSV62788601, COSV62790808; called by muse, mutect2, varscan2
- ADAMTS15 | c.2232G>A p.S744= | Silent (SNP) | VAF 26/133 reads (20%) | catalogued as rs544957547, COSV54507693; called by muse, mutect2, varscan2
- ADCK1 | c.975G>A p.A325= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as rs1469204186, COSV53082997; called by muse, mutect2, varscan2
- ADGRF5 | c.1431G>A p.P477= | Silent (SNP) | VAF 34/48 reads (71%) | catalogued as rs748771069, COSV51936916; called by muse, mutect2, varscan2
- ARHGEF1 | c.765G>A p.S255= | Silent (SNP) | VAF 35/66 reads (53%) | catalogued as rs782763644, COSV61528623; called by muse, mutect2, varscan2
- C2orf68 | c.423G>A p.T141= | Silent (SNP) | VAF 51/76 reads (67%) | catalogued as rs746075456, COSV60473025; called by muse, mutect2, varscan2
- CDC42BPB | c.3573G>A p.S1191= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as rs757474859, COSV63475327; called by muse, mutect2, varscan2
- COL27A1 | c.2547C>T p.P849= | Silent (SNP) | VAF 233/316 reads (74%) | catalogued as rs144760825; called by muse, mutect2, varscan2
- COL4A2 | c.753C>T p.N251= | Silent (SNP) | VAF 55/69 reads (80%) | catalogued as rs763026854, COSV64624841; called by muse, mutect2, varscan2
- CPA1 | c.285G>A p.S95= | Silent (SNP) | VAF 50/131 reads (38%) | catalogued as rs782095540, COSV50568133; called by muse, mutect2, varscan2
- CYP21A2 | c.972C>T p.H324= | Silent (SNP) | VAF 36/50 reads (72%) | catalogued as rs773218988, COSV64483172; called by muse, mutect2, varscan2
- DAB2IP | c.1530G>A p.P510= (on ENST00000408936; = p.P482= on NM_032552.3) | Silent (SNP) | VAF 85/109 reads (78%) | catalogued as rs372045771; called by muse, mutect2, varscan2
- DNM2 | c.414G>A p.P138= | Silent (SNP) | VAF 62/424 reads (15%) | catalogued as rs1222869455, COSV58965124; called by muse, mutect2, varscan2
- EEF1A2 | c.525C>T p.S175= | Silent (SNP) | VAF 64/84 reads (76%) | catalogued as rs780009006, COSV53207105; called by muse, mutect2, varscan2
- FCGBP | c.6558G>A p.S2186= | Silent (SNP) | VAF 108/286 reads (38%) | catalogued as rs762580580, COSV55452357; called by muse, mutect2, varscan2
- FLNA | c.4221C>T p.D1407= | Silent (SNP) | VAF 178/227 reads (78%) | catalogued as rs372110377, COSV61041354; called by muse, mutect2, varscan2
- FOXRED1 | c.429C>T p.A143= | Silent (SNP) | VAF 84/134 reads (63%) | catalogued as rs746956683, COSV55006622; called by muse, mutect2, varscan2
- FPR1 | c.951C>T p.P317= | Silent (SNP) | VAF 118/149 reads (79%) | catalogued as rs570072877, COSV59051130; called by muse, mutect2, varscan2
- GPR153 | c.543C>T p.G181= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs777005637, COSV64938749; called by muse, mutect2, varscan2
- GRIN2D | c.2274C>T p.Y758= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs749410602, COSV53517865; ClinVar: likely benign; called by muse, mutect2, varscan2
- KALRN | c.1014G>A p.T338= | Silent (SNP) | VAF 106/188 reads (56%) | catalogued as rs746433667, COSV53772334; called by muse, mutect2, varscan2
- KIF1A | c.174G>A p.S58= | Silent (SNP) | VAF 48/70 reads (69%) | catalogued as rs369088708; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRRK1 | c.2598C>T p.D866= | Silent (SNP) | VAF 17/25 reads (68%) | catalogued as rs535655027, COSV52618886; called by muse, mutect2, varscan2
- MAPK4 | c.858C>T p.I286= | Silent (SNP) | VAF 86/208 reads (41%) | catalogued as COSV68542846; called by muse, mutect2, varscan2
- MLLT1 | c.738G>A p.P246= | Silent (SNP) | VAF 36/47 reads (77%) | catalogued as rs774416477, COSV53131711; called by muse, mutect2, varscan2
- MYBL1 | c.1038C>T p.N346= | Silent (SNP) | VAF 35/40 reads (88%) | catalogued as rs150212945; called by muse, mutect2, varscan2
- NCAN | c.3522G>A p.P1174= | Silent (SNP) | VAF 62/80 reads (78%) | catalogued as rs1008744871, COSV53054268; called by muse, mutect2, varscan2
- NPC1 | c.1146A>G p.S382= | Silent (SNP) | VAF 27/81 reads (33%) | catalogued as COSV52580955; called by muse, mutect2, varscan2
- NPLOC4 | c.1215C>T p.D405= | Silent (SNP) | VAF 76/106 reads (72%) | catalogued as rs372434085; called by muse, mutect2, varscan2
- NRF1 | c.1152G>A p.S384= | Silent (SNP) | VAF 63/156 reads (40%) | catalogued as rs767037669, COSV56214277; called by muse, mutect2, varscan2
- NTNG2 | c.705G>A p.T235= | Silent (SNP) | VAF 102/141 reads (72%) | catalogued as COSV62367759; called by muse, mutect2, varscan2
- NUDC | c.237C>T p.A79= | Silent (SNP) | VAF 29/36 reads (81%) | catalogued as rs762308144, COSV58325797; called by muse, mutect2, varscan2
- P2RX3 | c.1104C>A p.I368= | Silent (SNP) | VAF 32/33 reads (97%) | catalogued as rs377490584, COSV54443596, COSV54444467; called by muse, mutect2
- PAPOLB | c.798G>A p.A266= | Silent (SNP) | VAF 130/305 reads (43%) | catalogued as rs112213840; called by muse, mutect2, varscan2
- PCDHB13 | c.1788G>A p.S596= | Silent (SNP) | VAF 44/106 reads (42%) | catalogued as COSV99507670; called by muse, mutect2, varscan2
- PCDHGB6 | c.1617G>A p.S539= | Silent (SNP) | VAF 18/20 reads (90%) | catalogued as rs781534809, COSV53912228; called by muse, mutect2, varscan2
- PLEKHG3 | c.2463G>A p.P821= (on ENST00000394691; = p.P877= on NM_001308147.2) | Silent (SNP) | VAF 62/86 reads (72%) | catalogued as rs745722450, COSV55981553; called by muse, mutect2, varscan2
- PRDM16 | c.2067C>T p.A689= | Silent (SNP) | VAF 97/122 reads (80%) | catalogued as rs371813954, COSV54586793; ClinVar: likely benign; called by muse, mutect2, varscan2
- PTPRN2 | c.2553C>T p.N851= | Silent (SNP) | VAF 10/198 reads (5%) | catalogued as COSV66104879; called by muse, mutect2
- RELN | c.7605C>T p.N2535= | Silent (SNP) | VAF 68/172 reads (40%) | catalogued as rs750764421, COSV59017186; called by muse, mutect2, varscan2
- RGR | c.309G>A p.A103= | Silent (SNP) | VAF 66/101 reads (65%) | catalogued as rs373030585; called by muse, mutect2, varscan2
- RNF165 | c.960C>T p.C320= | Silent (SNP) | VAF 32/256 reads (13%) | catalogued as rs1334292305, COSV53970752; called by muse, mutect2, varscan2
- RPA1 | c.684C>T p.D228= | Silent (SNP) | VAF 16/22 reads (73%) | catalogued as rs376851045; called by muse, mutect2, varscan2
- RXFP1 | c.1350C>T p.A450= | Silent (SNP) | VAF 32/161 reads (20%) | catalogued as rs373779528; called by muse, mutect2, varscan2
- SEC16A | c.5703G>A p.P1901= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs929922939, COSV51530289; called by muse, mutect2, varscan2
- SERPINA5 | c.1089G>A p.A363= | Silent (SNP) | VAF 322/436 reads (74%) | catalogued as rs749307094, COSV61574530; called by muse, mutect2, varscan2
- SOX6 | c.1716G>A p.R572= (on ENST00000528429 / NM_001145819.2; = p.R545= on NM_017508.3) | Silent (SNP) | VAF 3/41 reads (7%) | catalogued as rs1323965811, COSV57051384; called by muse, mutect2
- SPATS2L | c.1131C>T p.H377= | Silent (SNP) | VAF 14/142 reads (10%) | catalogued as rs376312723; called by muse, mutect2, varscan2
- SPTBN4 | c.1413C>T p.H471= | Silent (SNP) | VAF 29/38 reads (76%) | catalogued as rs777037117, COSV58946382; called by muse, mutect2, varscan2
- SPTBN5 | c.8028T>C p.H2676= | Silent (SNP) | VAF 23/30 reads (77%) | catalogued as rs773355575, COSV58024185; called by muse, mutect2, varscan2
- SRCIN1 | c.3360C>T p.I1120= (on ENST00000621492; = p.I1086= on NM_025248.3) | Silent (SNP) | VAF 118/166 reads (71%) | catalogued as rs745505032; called by muse, mutect2, varscan2
- STARD13 | c.600C>T p.S200= (on ENST00000336934 / NM_001243476.3; = p.S82= on NM_052851.3) | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as rs778828160, COSV55233557; called by muse, mutect2, varscan2
- TAB2 | c.360A>G p.E120= | Silent (SNP) | VAF 67/90 reads (74%) | catalogued as rs765640727, COSV53853741; called by muse, mutect2, varscan2
- TMF1 | c.819G>A p.A273= | Silent (SNP) | VAF 42/58 reads (72%) | catalogued as rs749655632, COSV68373649; called by muse, mutect2, varscan2
- TNS3 | c.3066C>T p.F1022= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as rs762256329, COSV60794579; called by muse, mutect2, varscan2
- TSPAN17 | c.225G>A p.S75= | Silent (SNP) | VAF 98/129 reads (76%) | catalogued as COSV53781074; called by muse, mutect2, varscan2
- TSSK2 | c.921C>T p.P307= | Silent (SNP) | VAF 45/64 reads (70%) | catalogued as rs150037057; called by muse, mutect2, varscan2
- UBE2O | c.1668C>T p.D556= | Silent (SNP) | VAF 134/169 reads (79%) | catalogued as rs184947149, COSV60060633, COSV60065222; called by muse, mutect2, varscan2
- ULK1 | c.1134G>A p.P378= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as rs561387032, COSV58855172; called by muse, mutect2, varscan2
- WRNIP1 | c.1179C>T p.I393= | Silent (SNP) | VAF 50/80 reads (63%) | catalogued as rs1261256493, COSV66356207; called by muse, mutect2, varscan2
- ZNF107 | c.2169A>G p.E723= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV61330132; called by muse, mutect2, varscan2
- ZNF623 | c.117G>A p.T39= | Silent (SNP) | VAF 80/110 reads (73%) | catalogued as rs201671001, COSV71697120; called by muse, mutect2, varscan2
- AL662899.2 | c.367+257G>A | Intron (SNP) | VAF 8/118 reads (7%) | catalogued as rs778849848, COSV101021710, COSV65508026; called by muse, mutect2
- NDUFV3 | c.170-4929C>T | Intron (SNP) | VAF 106/160 reads (66%) | catalogued as rs749517661, COSV100447119; called by muse, mutect2, varscan2
- TMEM183B | n.536C>T | RNA (SNP) | VAF 127/172 reads (74%) | catalogued as rs372354699; called by muse, mutect2, varscan2
- Y_RNA | chr7:74896478 G>A | 3'Flank (SNP) | VAF 25/30 reads (83%) | catalogued as rs587706525; called by muse, mutect2, varscan2
